EXCEPTIONAL_RESPONDERS case ER-B1PV — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6e912506-29c8-4fce-993c-2a7d75854b7f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1960; Vital status: Alive.

Diagnoses (1)
1. Ductal carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 53.9 years (19,682 days); Year of diagnosis: 2014; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,150 days (3.1 years); Days to best overall response: 1,139 days (3.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Pertuzumab + Trastuzumab; Days to treatment start: 43 days.

Follow-up (1 entry)
- Days to follow up: 1,150 days (3.1 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 29 days; Days progression-free: 1,150 days (3.1 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B1PV-TTM1-A: Sample type: Slides; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B1PV-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 22; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 6.
- Sample ER-B1PV-TTP1-A: Sample type: Slides; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B1PV-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 19; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 6.
